Somatic mutation profile of tumor specimen MMRF_1662_1_BM_CD138pos (aliquot MMRF_1662_1_BM_CD138pos_T2_KBS5U_K11933) from MMRF case MMRF_1662, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 78.3 years (28,583 days).
Specimen MMRF_1662_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f31dd0b-9b2a-4774-95e2-eabd98cc521d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1662_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1662_1_PB_Whole_C7_KBS5U_K11903; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96e364d8-5e1e-40ee-92f0-24f748ebcc1f

The open-access MAF lists 62 somatic variants for this specimen: 18 protein-altering or splice-affecting, 8 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 21, Missense Mutation 12, Intron 9, Silent 8, 5'UTR 5, Nonsense Mutation 3, In Frame Del 1, Splice Site 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.227A>G p.E76G | Missense Mutation (SNP) | VAF 38/89 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs121918465, CM112765, CM1314032, CM137734, COSV61005372, COSV61006382, COSV61007426; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- H1-4 | c.243G>C p.K81N | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as rs200686576, COSV56800958; called by muse, mutect2, varscan2
- IGLV3-1 | c.47G>C p.G16A | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.529); catalogued as rs144850905; called by muse, varscan2
- NIPAL1 | c.206A>T p.Y69F | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as rs1381941963; called by muse, mutect2, varscan2
- RFNG | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs1273072952; called by muse, mutect2, varscan2
- STON1 | c.723C>A p.N241K | Missense Mutation (SNP) | VAF 153/266 reads (58%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as rs992622457; called by muse, mutect2, varscan2
- ZFHX4 | c.5062C>A p.P1688T | Missense Mutation (SNP) | VAF 124/326 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV50972083; called by muse, mutect2, varscan2
- ABCB8 | c.615+2T>C p.X205_splice (on ENST00000297504 / NM_001282291.2; = p.X188_splice on NM_007188.5) | Splice Site (SNP) | VAF 17/166 reads (10%) | called by muse, mutect2
- CSMD3 | c.6989C>T p.T2330I (on ENST00000297405 / NM_001363185.1; = p.T2226I on NM_052900.3) | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- DESI2 | c.158_181del p.F53_A60del | In Frame Del (DEL) | VAF 9/41 reads (22%) | called by mutect2, pindel
- FAM120A | c.2170C>T p.Q724* | Nonsense Mutation (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- FAN1 | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 134/267 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- H2AC17 | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- HIC1 | c.959G>A p.G320D (on ENST00000322941 / NM_001098202.1; = p.G301D on NM_006497.4) | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.284); called by muse, mutect2
- KDSR | c.69del p.S24Afs*36 | Frame Shift Del (DEL) | VAF 25/108 reads (23%) | called by mutect2, pindel, varscan2
- SLC44A5 | c.987G>A p.M329I | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.065); called by muse, mutect2
- SP9 | c.677C>A p.S226* | Nonsense Mutation (SNP) | VAF 7/128 reads (5%) | called by muse, mutect2
- SRRM2 | c.5699C>G p.S1900* | Nonsense Mutation (SNP) | VAF 15/234 reads (6%) | called by muse, mutect2
- CASZ1 | c.4377C>T p.C1459= | Silent (SNP) | VAF 24/57 reads (42%) | called by muse, mutect2, varscan2
- DTX1 | c.162G>A p.E54= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV57501098; called by muse, mutect2, varscan2
- IGHV2-70 | c.156A>T p.G52= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as rs1232476476; called by muse, varscan2
- KIAA0319L | c.1146T>A p.I382= | Silent (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- LVRN | c.1542T>C p.S514= | Silent (SNP) | VAF 73/139 reads (53%) | catalogued as COSV100773462; called by muse, mutect2, varscan2
- PC | c.1633C>T p.L545= | Silent (SNP) | VAF 77/120 reads (64%) | catalogued as COSV58921884; called by muse, mutect2, varscan2
- PCDHA9 | c.2199G>A p.A733= | Silent (SNP) | VAF 57/106 reads (54%) | catalogued as rs373763041; called by muse, mutect2, varscan2
- ZGRF1 | c.6138T>C p.N2046= | Silent (SNP) | VAF 50/176 reads (28%) | called by muse, mutect2, varscan2
- ART4 | c.*3217T>G | 3'UTR (SNP) | VAF 38/100 reads (38%) | called by muse, mutect2, varscan2
- ART4 | c.*3102A>G | 3'UTR (SNP) | VAF 55/116 reads (47%) | called by muse, mutect2, varscan2
- ART4 | c.*2971T>G | 3'UTR (SNP) | VAF 29/60 reads (48%) | called by muse, mutect2, varscan2
- BMP5 | c.*416A>C | 3'UTR (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.*1472T>A | 3'UTR (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- CASP10 | c.1415+8814del | Intron (DEL) | VAF 21/44 reads (48%) | called by mutect2, pindel, varscan2
- CDK20 | c.563+57C>T | Intron (SNP) | VAF 10/174 reads (6%) | called by muse, mutect2
- CEP350 | c.-76G>A | 5'UTR (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- CNTN5 | c.2730+111T>G | Intron (SNP) | VAF 41/142 reads (29%) | called by muse, mutect2, varscan2
- CPSF4 | c.571-58C>T | Intron (SNP) | VAF 46/128 reads (36%) | called by mutect2, varscan2
- CTAGE1 | c.*1143C>T | 3'UTR (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- ENO2 | c.*216C>G | 3'UTR (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2, varscan2
- ERCC6 | c.*1448T>G | 3'UTR (SNP) | VAF 22/53 reads (42%) | catalogued as rs569800283; called by muse, mutect2, varscan2
- FSCN3 | c.960+80G>A | Intron (SNP) | VAF 5/85 reads (6%) | called by muse, mutect2
- GALNT13 | c.*2165T>C | 3'UTR (SNP) | VAF 83/122 reads (68%) | called by muse, mutect2, varscan2
- GDNF | c.*2817T>A | 3'UTR (SNP) | VAF 39/90 reads (43%) | called by muse, mutect2, varscan2
- GRIK3 | c.*5217C>T | 3'UTR (SNP) | VAF 45/103 reads (44%) | catalogued as rs547330908, COSV66139684; called by muse, mutect2, varscan2
- KCTD1 | c.-15-46367T>A | Intron (SNP) | VAF 33/93 reads (35%) | called by muse, mutect2, varscan2
- KLF9 | c.-644G>T | 5'UTR (SNP) | VAF 89/286 reads (31%) | called by muse, mutect2, varscan2
- MYLIP | c.*546T>G | 3'UTR (SNP) | VAF 35/76 reads (46%) | called by muse, mutect2, varscan2
- NBEA | c.*1078C>G | 3'UTR (SNP) | VAF 23/46 reads (50%) | catalogued as rs1566491503; called by muse, mutect2, varscan2
- NET1 | c.*1016G>C | 3'UTR (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- OTULIN | c.*8A>T | 3'UTR (SNP) | VAF 85/132 reads (64%) | called by muse, mutect2, varscan2
- PABPC3 | c.*81del | 3'UTR (DEL) | VAF 78/180 reads (43%) | catalogued as rs1273736635, COSV55797202; called by mutect2, varscan2
- PARP6 | c.-65C>T | 5'UTR (SNP) | VAF 38/90 reads (42%) | catalogued as rs752177770, COSV99536371; called by muse, mutect2, varscan2
- PLXNA4 | c.1372-85533C>A | Intron (SNP) | VAF 60/95 reads (63%) | called by muse, mutect2, varscan2
- POU6F1 | chr12:51188196 G>A | 3'Flank (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- RNF2 | c.*1479T>C | 3'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- SLIT3 | c.*3995del | 3'UTR (DEL) | VAF 58/156 reads (37%) | called by mutect2, varscan2
- TIGD7 | c.-217T>A | 5'UTR (SNP) | VAF 54/119 reads (45%) | called by muse, mutect2, varscan2
- UACA | c.*848C>T | 3'UTR (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- UBE3A | c.2507+151C>T | Intron (SNP) | VAF 6/12 reads (50%) | catalogued as rs1025248595; called by muse, mutect2, varscan2
- UBE3A | c.2507+150G>T | Intron (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- VASH1 | c.*2026C>T | 3'UTR (SNP) | VAF 19/40 reads (48%) | catalogued as rs888976671; called by muse, mutect2, varscan2
- VCPIP1 | c.*2899G>A | 3'UTR (SNP) | VAF 63/134 reads (47%) | called by muse, mutect2, varscan2
- ZNF671 | c.-29G>A | 5'UTR (SNP) | VAF 64/219 reads (29%) | catalogued as rs1441291120; called by muse, mutect2, varscan2
